Gene-level copy-number profile of tumor specimen HCM-SANG-0283-C18-01A-01D-A80T-32 from HCMI case HCM-SANG-0283-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0283-C18-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6051f50a-1ce5-45ff-aeab-e8519b52b2b4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0283-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,754 have no estimate.
https://portal.gdc.cancer.gov/files/45a58992-a7aa-447a-9315-27ab6f1f4d2d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 581; copy number 1: 1,100; copy number 2: 2,196; copy number 3: 16,819; copy number 4: 17,957; copy number 5: 11,829; copy number 6: 2,825; copy number 7: 1,883; copy number 8: 2,016; copy number 9: 766; copy number 10: 886; copy number 11: 3; copy number 14: 4; copy number 15: 3; copy number 21: 1.

Homozygous deletions (total copy number 0; autosomes only): 69 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,498,785–144,068,350, 24 genes: AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D.
- chr6:32,578,769–32,589,848, 1 gene: HLA-DRB1.
- chr11:112,967–186,136, 5 genes (within-gene range 0–4): AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P.
- chr15:101,903,154–101,979,093, 10 genes: AC140725.2, OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.
- chr18:1,927,727–1,929,094, 1 gene (within-gene range 0–3): AIDAP3.
- chr22:18,340,145–18,894,407, 28 genes: GGTLC5P, FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4, FAM230E, GGT3P, AC008132.2, E2F6P1, AC008132.1, BCRP7, FAM230F, AC008103.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,663 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:117,549,415–118,185,228, 10 genes, copy number 9: VPS25P1, AL157902.1, TENT5C, VDAC2P3, AL390877.1, AL390877.2, PNRC2P1, GDAP2, WDR3, SPAG17.
- chr6:32,517,353–32,530,287, 1 gene, copy number 14: HLA-DRB5.
- chr7:484,107–31,708,455, 535 genes, copy number 9–10 (broad region; genes not listed).
- chr7:39,545,646–40,134,622, 22 genes, copy number 9: AC011290.1, YAE1, AC011290.2, AC004837.3, AC004837.1, RALA, AC004837.2, LINC00265, RNU6-719P, AC004987.3, CICP22, AC004987.2, AC004987.1, SSBL3P1, RWDD4P2, RN7SL496P, AC072061.1, CDK13, AC006023.2, AC006023.1, MPLKIP, Y_RNA.
- chr7:42,661,716–65,508,944, 451 genes, copy number 9–11 (broad region; genes not listed).
- chr9:39,886,861–40,106,527, 4 genes, copy number 15–21: RN7SL763P, SNORA70, CR769767.1, AL773545.3.
- chr9:65,189,995–65,230,861, 3 genes, copy number 14: BMS1P12, AL512605.1, AL512605.2.
- chr10:38,783,004–38,783,108, 1 gene, copy number 9: AL590623.1.
- chr13:18,467,172–20,962,195, 84 genes, copy number 9–10 (broad region; genes not listed).
- chr13:75,283,503–75,482,169, 2 genes, copy number 10: TBC1D4, AL139230.1.
- chr13:79,311,824–79,427,317, 3 genes, copy number 9: RBM26, RNA5SP33, RBM26-AS1.
- chr20:3,249,305–3,410,036, 5 genes, copy number 9: C20orf194, RNU6-1019P, UBE2V1P1, U3, AL117334.1.
- chr20:5,532,878–6,040,053, 17 genes, copy number 9: RPS18P1, AL109935.1, GPCPD1, EIF4EP1, SHLD1, RNU1-55P, CHGB, KANK1P1, TRMT6, MCM8, AL035461.3, Y_RNA, AL035461.1, MCM8-AS1, AL035461.2, RN7SL498P, CRLS1.
- chr20:24,469,629–24,666,616, 1 gene, copy number 10 (within-gene range 7–10): SYNDIG1.
- chr20:24,679,547–39,039,723, 339 genes, copy number 9–10 (broad region; genes not listed).
- chr20:43,189,998–48,827,999, 179 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr20:53,544,615–53,827,297, 6 genes, copy number 9: Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1.

Autosomal genes at a single copy (total copy number 1): 1,100. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
